Gene-level copy-number profile of tumor specimen ALCH-B277-TTP1-A from ALCHEMIST case ALCH-B277, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,088 days).
Specimen ALCH-B277-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e729cd2f-6ba1-4f43-b5fd-3485444eb314.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B277-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/a3c38333-3452-4f21-b16c-b1a63a0b90f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 16,555; copy number 2: 40,945; copy number 3: 1,356; copy number 32: 7; copy number 34: 29; copy number 35: 16.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:197,578,213–197,635,811, 3 genes (within-gene range 0–1): AC132008.2, AC132008.1, AC024560.2.
- chr8:38,386,207–38,409,527, 1 gene (within-gene range 0–1): LETM2.
- chr8:38,408,048–38,408,742, 1 gene (within-gene range 0–1): AC087623.3.
- chr9:125,372,325–125,372,766, 1 gene: AL627223.1.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr20:3,846,799–3,876,123, 1 gene: MAVS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 52 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:80,034,745–81,112,068, 29 genes, copy number 34 (within-gene range 3–34): TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2.
- chr8:116,402,543–116,944,487, 7 genes, copy number 32: AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD.
- chr8:127,578,473–128,564,679, 16 genes, copy number 35: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.

Autosomal genes at a single copy (total copy number 1): 13,699. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
